Surgical pathology report (de-identified scan), TCGA case TCGA-43-3920, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-3920-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Level 10
- B. Level 11
- C. Level 12
- D. Right upper lobe
- E. 2R
- F. 4R
- G. Level 8
- H. Level 7
- I. Level 9

CLINICAL NOTES

GROSS DESCRIPTION

A. Received fresh, subsequently fixed in formalin labeled "level 10" is a 1 x 0.8 x 0.4 cm. black-tan irregular soft tissue fragment which is bisected and entirely submitted in one cassette. AS-1

B. Received fresh, subsequently fixed in formalin labeled "level 11" is a 0.9 x 0.6 x 0.4 cm. pink-black irregular soft tissue fragment. The specimen is bisected and entirely submitted in one cassette. AS-1

C. Received fresh, subsequently fixed in formalin labeled "level 12" are two black-tan irregular soft tissue fragments which are 1.8 cm. and 1 cm. in greatest dimension. The specimens are entirely submitted in one cassette. AS-1

D. Received fresh, subsequently fixed in formalin labeled "right upper lobe" is a 15 x 14 x 5 cm. lobe of lung. The specimen shows a 3.5 cm. indurated focus on the pleura. This area is inked blue. The specimen is sectioned to show a large white tan indurated mass which is 5.0 x 5.0 x 4.5 cm. This specimen is sectioned to show the tumor coming within 1.5 cm. from the surgical stapled margin (inked black). This also comes within 3.5 cm. from

GROSS DESCRIPTION

the hilum. The tumor mass is firm and indurated. The remainder of the cut surface shows a pink-red spongy parenchyma. No discrete hilar nodes are grossly identified. Representative sections of the specimen are submitted as follows: Block 1, 2 - tumor to pleura; block 3 - tumor to surgical margin; block 4 - tumor to normal; block

5 - representative normal; block 6 - hilar and vascular margins; block 7 - possible hilar nodes. RS-7.

E. Received fresh, subsequently fixed in formalin labeled "2R" are three yellow-red fatty tissue fragments which may contain possible lymphoid tissue. These range from 0.6 cm. to 1.2 cm. in greatest dimension. The specimens are entirely submitted in one cassette. AS-1

[page 2 of 3]
F. Received fresh, subsequently fixed in formalin labeled "4R" is a 1.2 cm. pink fleshy nodule which shows black discoloration on cut surface. There is also a minute aggregate measuring 0.4 x 0.3 x 0.2 cm. The larger is bisected and the specimens are entirely submitted as follows: block 1 - larger lymph node; 2 - smaller aggregate.

G. Received fresh, subsequently fixed in formalin labeled "level 8" is a 0.6 x 0.4 x 0.3 cm. pink-red irregular soft tissue fragment which is entirely submitted in one cassette. AS-1

H. Received fresh, subsequently fixed in formalin labeled "level 7" is an aggregate of yellow-pink-red irregular soft tissue fragment which may contain lymphoid tissue measuring 1.5 x 0.8 x 0.3 cm. The specimens are entirely submitted in one cassette. AS-1

I. Received fresh, subsequently fixed in formalin labeled "level 9" are two black-pink irregular soft tissue fragments which are 1.2 cm. and 0.5 cm. in greatest dimension. The specimens are entirely submitted in one cassette with the larger bi-valved. The specimens are entirely submitted in one cassette. AS-1

GROSS DESCRIPTION

MICROSCOPIC DESCRIPTION

A-C. Sections of the level 10, level 11, and level 12 lymph nodes demonstrate no evidence of metastatic disease in one lymph node each.

D. The following template applies to the right upper lobe:

Histologic type: Squamous cell carcinoma.
Histologic grade: Poorly differentiated
Primary tumor: measures 5 cm, (pT2):
Margins of resection: Uninvolved.
Direct extension of tumor: Not identified.
Venous (large vessel) invasion: Not identified.
Arterial (large vessel) invasion: Not identified.
Lymphatic (small vessel) invasion: Not identified.
Regional lymph nodes (pN): Negative as described in other specimens (pN0).
Distant metastasis (pM): Cannot evaluated by this specimen (pMX).
Other findings: Four lymph nodes are negative for metastatic disease.

E. There is no evidence of metastatic disease to four 2R

[page 3 of 3]
lymph nodes.
F. There is no evidence of metastatic disease to 3 4R
lymph
nodes.
G. There is no evidence of metastatic disease to one level
8 lymph node.
H. There is no evidence of metastatic disease to four
level
7 lymph nodes.
I. There is no evidence of metastatic disease to two level
9 lymph nodes.

MICROSCOPIC DESCRIPTION

3x7, 4x2

DIAGNOSIS

- A. Level 2 lymph node, resection -
No evidence of resection to one lymph node (0/1).
- B. Level 11 lymph node, resection -
No evidence of metastasis to one lymph node (0/1).
- C. Level 12 lymph nodes, resection -
No evidence of metastasis to one lymph node (0/1).
- D. Lung, right upper lobe, lobectomy -
Poorly differentiated squamous cell carcinoma, 5 cm. in
greatest dimension.
Surgical margins uninvolved.
Four lymph nodes with no evidence of metastatic disease.
- E. 2R lymph nodes, resection -
No evidence of metastasis to 4 lymph nodes (0/4).
- F. 4R lymph nodes, resection -
No evidence of metastasis to 3 lymph nodes (0/3).
- G. Level 8 lymph node, resection -
No evidence of metastasis to 1 lymph node (0/1).
- H. Level 7 lymph node, resection -
No evidence of metastasis to 4 lymph nodes (0/4).
- I. Level 9 lymph node, resection -
No evidence of metastasis to 2 lymph nodes (0/2).

--- End Of Report ---

Source: NCI Genomic Data Commons file 580beae0-51ae-4299-af91-bd74cce0db93 (TCGA-43-3920.93F563A8-23E6-4A60-A7CA-B51AB176F978.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).